Somatic mutation profile of tumor specimen TARGET-30-PALSAE-01A (aliquot TARGET-30-PALSAE-01A-01W) from TARGET case TARGET-30-PALSAE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 2.1 years (782 days).
Specimen TARGET-30-PALSAE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c188a610-90b6-4bce-8c2f-1b1f0f48afd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALSAE-10A (Blood Derived Normal), aliquot TARGET-30-PALSAE-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79d79d33-5b2a-40bd-8118-b4c3b556e7c1

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2B1 | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV53805064, COSV53807289; called by muse, mutect2, varscan2
- CSF1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs750913335, COSV60032197; called by muse, mutect2, varscan2
- FOXA1 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.602); catalogued as rs1484270927, COSV51644524; called by muse, mutect2
- KCNH3 | c.2089C>T p.R697* | Nonsense Mutation (SNP) | VAF 28/61 reads (46%) | catalogued as COSV57789938; called by muse, mutect2, varscan2
- MAN2A2 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.735); catalogued as COSV64637437; called by muse, mutect2, varscan2
- SORL1 | c.3502G>A p.G1168S | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376552061, COSV52750845; called by muse, mutect2, varscan2
- BLM | c.362C>A p.T121N | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- POLDIP3 | c.19del p.D7Tfs*92 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, varscan2
- RAPH1 | c.3075dup p.K1026Qfs*47 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by pindel, varscan2
- GALNT18 | c.456C>T p.S152= | Silent (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
- OVOL2 | c.627G>A p.R209= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV53860974; called by muse, mutect2
